Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7398, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7398-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) NECK, LEFT LEVEL 2, EXCISION: NO TUMOR IDENTIFIED IN ONE LYMPH NODE (0/1).
- 2) SOFT TISSUE, PETIOLE, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 3) MUCOSA, RIGHT MEDIAL ARYTENOID, BIOPSY: DETACHED ATYPICAL CELLS WITH CAUTERY EFFECT, NOT DIAGNOSTIC OF MALIGNANCY.
- 4) MUCOSA, LEFT MEDIAL ARYTENOID, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 5) MUCOSA, BASE OF TONGUE, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 6) MUCOSA, RIGHT PYRIFORM SINUS, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 7) MUCOSA, LEFT PYRIFORM SINUS, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 8) NECK; LEVELS 2, 3, & 4, RIGHT, DISSECTION: NO TUMOR IDENTIFIED IN NINE LYMPH NODES (0/9).
- 9) NECK, LEVELS 2, 3, & 4, LEFT, DISSECTION: NO TUMOR IDENTIFIED IN TWELVE LYMPH NODES (0/12).
- 10) NECK, LEVEL 4 NODE, LEFT, EXCISION: NO TUMOR IDENTIFIED IN ONE LYMPH NODE (0/1).
- 11) LARYNX, SUPRAGLOTTIC, RIGHT, EXCISION: BASALOID SQUAMOUS CELL CARCINOMA INVOLVING THE EPIGLOTTIS (1.3 CM); NO DEFINITIVE PERINEURAL OR LYMPHOVASCULAR SPACE INVASION IDENTIFIED.
- 12) LARYNX, SUPRAGLOTTIC, LEFT, EXCISION: BASALOID SQUAMOUS CELL CARCINOMA INVOLVING THE EPIGLOTTIS (2.1 CM); NO DEFINITIVE PERINEURAL OR LYMPHOVASCULAR SPACE INVASION IDENTIFIED.
- 13) BASE OF TONGUE, EXCISION: BASALOID SQUAMOUS CELL CARCINOMA (1.3 CM); NO DEFINITIVE PERINEURAL OR LYMPHOVASCULAR SPACE INVASION IDENTIFIED.

Upper Aerodigestive Tract-including Minor Salivary Glands, Lip, Oral cavity, Nasal Cavity, Paranasal Sinuses, Oropharynx, Nasopharynx, and Hypopharynx Summary of Findings:

Specimen Type: supraglottic laryngectomy

[REDACTED]

[page 2 of 6]
Tumor Site: epiglottis and base of tongue

Tumor Size: at least 2.1 cm

Laterality:

Right

Left

☒ Bilateral

Midline

Not specified

Margins (select all that apply)

Cannot be assessed

☒ Margin uninvolved by invasive carcinoma

(per margins taken at frozen section)

Margin involved by invasive carcinoma

Margins uninvolved by carcinoma in situ

(Specify distance to closest margins)

Margins involved by carcinoma in situ

Not applicable

Histologic Type: basaloid squamous cell carcinoma

Histologic Grade: moderately differentiated

Pathologic Staging (pTMN)

Primary tumor (pT): T2

Regional Lymph Nodes (pN): 0

Number examined: 23

Numbered involved: 0

Perineural invasion: (Select one)

Yes

☒ No

Not evaluable

Bony/Cartilage Invasion: (Select one)

☒ Yes

No

Not evaluable

Lymph-Vascular invasion: (Select one)

Yes

☒ No

Not evaluable

HPV testing ordered: No (performed on oral cavity and oropharyngeal squamous cell carcinomas)

**Electronically Signed Out by

[REDACTED]

[REDACTED]

[REDACTED]

[page 3 of 6]
CLINICAL DATA

Clinical Diagnosis: Squamous cell carcinoma

Clinical Findings: [REDACTED] year-old female with supraglottic basaloid squamous cell carcinoma.

Previous pathology: [REDACTED]

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)level 2 nodes left, 2)soft tissue of petiole, 3)right medial arytenoid, 4)left medial arytenoid, 5)base of tongue, 6)right piriform sinus, 7)left piriform sinus, 8)right radical neck dissection 2, 3 4, 9)left radical neck dissection 2, 3, 4, 10)level 4 node left, 11)right supraglottic larynx, 12)left supraglottic larynx, 13)base of tongue

GROSS DESCRIPTION:

1) SOURCE: Level 2 Nodes-Left

Received fresh for frozen section labeled with the patient's name, medical record number, and "left level 2 nodes frozen" is a 2.2 x 1.0 x 0.5 cm, tan-red possible lymph node. The specimen is bisected to reveal tan-red, indurated cut surfaces. One touch preparation is made. One half of the lymph node is frozen. The remainder of the specimen is entirely submitted as follows.

Summary of sections: 1AFSC, one half of lymph node, 1/1;
1B, remaining half of lymph node, 1/1.

2) SOURCE: Soft Tissue of Petiole

Received fresh for frozen section is an irregular fragment of pink-tan tissue, measuring 1.1 x 0.7 x 0.4 cm submitted entirely for frozen section.
Summary of sections: 2AFSC, 1/1.

3) SOURCE: Right Medial Arytenoid

The specimen is received fresh for frozen section labeled "right medial arytenoid for frozen." The specimen consists of three red-brown soft tissue fragments measuring as follows: 0.4 x 0.3 x 0.2 cm; 0.3 x 0.2 x 0.1 cm; and 0.2 x 0.1 x 0.1 cm. The entire specimen is submitted for frozen section. Specimen is placed in a teabag prior to submitting it for permanent. Specimen is submitted as follows.
Summary of sections: 3AFSC, 3/1.

4) SOURCE: Left Medial Arytenoid

Received fresh in a container labeled with the patient's name and "left medial arytenoid for frozen" is a 0.3 x 0.3 x 0.2 cm piece of pink-tan soft tissue that is submitted in its entirety for frozen section evaluation.
Summary of sections: 4AFSC, 1/1.

[page 4 of 6]
5) SOURCE: Base of Tongue

The specimen is received fresh in a container labeled with the patient's name and "base of tongue" for frozen. The specimen is a 0.5 x 0.3 x 0.2 strip of mucosa that is entirely submitted for frozen section.

Summary of sections: 5AFSC, 1/1.

6) SOURCE: Right Piriform Sinus

The specimen is received fresh for frozen section and labeled "right piriform sinus for frozen." The specimen consists of a single red-tan soft tissue fragment measuring 0.5 x 0.4 x 0.2 cm. The specimen was entirely frozen. The specimen is placed in a teabag prior to submission for permanent section. The specimen is entirely submitted as follows:

Summary of sections: 6AFSC, 2/1, after the specimen fragmented.

7) SOURCE: Left Piriform Sinus

The specimen is received fresh for frozen section labeled "left piriform sinus for frozen." The specimen consists of a single red-tan soft tissue fragment measuring 0.4 x 0.3 x 0.2 cm. The specimen was entirely frozen prior to submission for permanent section. The specimen is placed in a teabag. Specimen is submitted as follows.

Summary of sections: 7AFSC, 1/1.

8) SOURCE: Right Radical Neck Dissection Levels 2,3,4

The specimen is received fresh labeled with the patient's name, medical record number and "right radical neck dissection levels 2,3,4." The specimen consists of a single portion of red-brown soft tissue measuring 4.5 x 2.3 x 1.4 cm. The specimen is palpated for lymph nodes. Multiple lymph nodes are noted ranging in size from 0.5 to 2.0 cm in greatest dimension. Specimen is representatively submitted as follows.

Summary of sections: 8A, 2/1, one lymph node bisected;

8B, 4/1, four possible nodes that have been differentially inked;

8C, 4/1, four possible nodes that have been differentially inked.

9) SOURCE: Left Radical Neck Dissection Levels 2,3,4

Received fresh labeled with the patient's name, medical record number and labeled "left radical neck dissection levels 2, 3 and 4". The specimen consists of a single portion of red-brown soft tissue measuring 3.6 x 3.2 x 1.1 cm. There are multiple possible lymph nodes palpated measuring in greatest dimension from 0.3-1.4 cm. The specimen is representatively submitted as follows.

Summary of sections: 9A, five possible nodes differentially inked, 5/1;

9B, three possible nodes differentially inked, (the blue node has been bisected), 4/1;

9C, three possible nodes, the uninked node has been bisected, 4/1;

9D, two possible nodes, 3/1.

10) SOURCE: Level 4 Node Left

[page 5 of 6]
Received fresh labeled with the patient's name, medical record number and "level 4 node left". The specimen consists of a portion of red-brown soft tissue measuring 1.2 x 0.8 x 0.3 cm. A single possible lymph node measuring 0.5 cm in greatest dimension is palpated. The probable node is inked red. The entire specimen is submitted in 10A, 3/1.

11) SOURCE: Right Supraglottic Larynx

Received fresh labeled "right supraglottic larynx". The specimen consists of an unoriented portion of red-brown soft tissue and mucosa measuring in total 3.7 x 1.6 x 0.8 cm. There is a pink-tan, smooth and glistening mucosal surface on one end of the specimen. On the opposite side of that there appears to be some brown-black cauterized tissue. The probable surgical cut margin is inked black. The opposite side is inked blue. The specimen is serially sectioned along the long axis. Photography of the specimen is taken. The specimen on sectioning demonstrates a white-tan, unremarkable soft tissue on section. The specimen is entirely submitted on cassettes 11A-1D.

Summary of sections: 11A, 1/1;
11B, 11;
11C, 1/1;
11D, 2/1.

12) SOURCE: Left Supraglottic Larynx

Received fresh labeled with the patient's name, medical record number and the designation "left supraglottic larynx". The specimen consists of a single brown-tan unoriented soft tissue fragment measuring 3.6 x 1.9 x 0.6 cm. There is a portion of pink-tan hemorrhagic mucosa overlying the yellow-tan lobulated soft tissue under which there is a probable surgical cut margin with brown-black, cauterized tissue. The surface of the mucosa also has an area of probable surgical cautery at the extreme end of the specimen. Prior to sectioning, the specimen is inked as follows: the probable surgical cut margin is inked black, the opposite side of the tissue is inked blue including the mucosa. The possible cut surface on the mucosa is inked red. Sectioning the specimen reveals white-tan soft tissue which is unremarkable. The specimen is serially sectioned and entirely submitted in cassettes 12A-12C.

Summary of sections: 12A, 2/1;
12B, 3/1;
12C, 2/1.

13) SOURCE: Base of Tongue

Received fresh labeled with the patient's name and the designation "base of tongue". The specimen consists of a single brown-red unoriented soft tissue fragment measuring 2.5 x 1.7 x 0.6 cm. There is a portion of probable tongue mucosa showing small papillae. The probable surgical margin has black-brown cauterized tissue. Prior to sectioning, the probable surgical margin is inked black. There is a white-tan lesion centrally located on the mucosa measuring 0.5 x 0.2 cm. This is found 0.3 cm from the nearest cut surface. The specimen is serially sectioned to reveal a red-tan underlying soft tissue. The tissue underlying the described lesion is grossly unremarkable. The specimen is entirely submitted as follows.

[page 6 of 6]
Summary of sections: 13A, 1/1;
13B, 1/1;
13C, 1/1.

Dictated by

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Level 2 Nodes-Left

FROZEN SECTION AND TOUCH PREPARATION DIAGNOSIS: BENIGN LYMPH NODE. [REDACTED]

2) SOURCE: Soft Tissue of Petiole

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]

3) SOURCE: Right Medial Arytenoid

FROZEN SECTION DIAGNOSIS: RARE DETACHED ATYPICAL CELLS, NOT DIAGNOSTIC OF MALIGNANCY. [REDACTED]

4) SOURCE: Left Medial Arytenoid

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]

5) SOURCE: Base of Tongue

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]

6) SOURCE: Right Pyriform Sinus

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]

7) SOURCE: Left Pyriform Sinus

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]

Electronically signed by: [REDACTED] Attending Pathologist

Source: NCI Genomic Data Commons file 4a9b00cf-af99-4276-809b-9431c7fdb072 (TCGA-CR-7398.0228A377-F6CB-4C99-9A65-54D09E928065.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).